Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A8BR, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A8BR-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

[REDACTED]

....

Clinical Diagnosis & History:

[REDACTED] with sarcoma of right leg.

Specimens Submitted:

1: SP: Radical resection, right thigh sarcoma

DIAGNOSIS:

1) THIGH, RIGHT; RADICAL RESECTION:

- MALIGNANT FIBROUS HISTIOCYTOMA WITH MYXOID AND PLEOMORPHIC AREAS,
MEASURING 7.0 CM. MARGINS OF EXCISION NEGATIVE FOR TUMOR. TUMOR APPROACHES
1.0 CM FROM MEDIAL MARGIN.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF
THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED
THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result	Special Stain	Comment
	S-100	
	EMA	
	SMA	
	DES CONT	
	AE1:AE3	

Gross Description:

1) The specimen is received fresh, labeled, "Radical resection, right thigh sarcoma". The specimen measures 17.0 cm from superior to inferior, 6.5 cm from medial to lateral and 13.0 cm from anterior to deep margin. The medial aspect is inked in black and the specimen is incised and fresh sterile tumor is procured for research and diagnostic purposes. The specimen has been sagittally sectioned from anterior to posterior revealing a 7.0 x 6.0 x 5.0 cm tan soft fleshy to focally myxoid and friable mass. The tumor is generally well-circumscribed and is located within the superficial

PATH
REPORT

** Continued on next page **

ICD-O-3
Histocytoma, fibrous malignant
pleomorphic 883613
Site B Thigh NOS C49.2
JW 11/22/13

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

----- Page 2 of 2
aspect of the adductor muscles. The tumor approaches 1.0 cm from the medial margin, 1.5 cm from the superior margin, 7.0 cm from the inferior margin and 2.5 cm from the deep margin. The specimen has been inked as follows: medial-black, lateral-green, superior-blue. Representative sections including the nearest margins are taken.

Summary of Sections:

U - undesignated

Summary of Sections:

Part 1: SP: Radical resection, right thigh sarcoma

Block	Sect.	Site	PCs
14		U	14

PATH
REPORT

** End of Report **

Source: NCI Genomic Data Commons file b36d7589-6995-4997-9ee2-d31923f3bae1 (TCGA-DX-A8BR.316E15D7-761F-428F-B85B-C326C0DBFEC1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).